Somatic mutation profile of tumor specimen TCGA-OR-A5JV-01A (aliquot TCGA-OR-A5JV-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JV, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 55.6 years (20,319 days).
Specimen TCGA-OR-A5JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7af8775-8a3f-442a-949f-43196bbf21df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JV-10A (Blood Derived Normal), aliquot TCGA-OR-A5JV-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f05c5525-5230-4f75-b86c-a3654ffe9782

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APCDD1L | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776892324, COSV64486065; called by muse, mutect2, varscan2
- BBS9 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99628649; called by muse, mutect2, varscan2
- MUC16 | c.19307G>T p.G6436V | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV67470260; called by muse, mutect2, varscan2
- POLRMT | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs527922669, COSV101648669; called by muse, varscan2
- ROBO2 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.14); catalogued as COSV59903912; called by muse, mutect2, varscan2
- SPICE1 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV55622668; called by muse, mutect2, varscan2
- TECRL | c.1008G>T p.W336C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67091325; called by muse, mutect2, varscan2
- ZP4 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs775909119; called by muse, mutect2, varscan2
- CABLES2 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CSMD1 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2
- DIDO1 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HAGH | c.258C>A p.D86E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL6 | c.906T>A p.N302K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRXN2 | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2
- PALLD | c.1956A>T p.K652N | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- PALLD | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- PKHD1 | c.8186C>G p.A2729G | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SI | c.5090C>G p.A1697G | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPINK5 | c.1232A>G p.E411G | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CD300LG | c.465C>T p.T155= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- DNAH3 | c.5244C>G p.P1748= | Silent (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- FHDC1 | c.1119G>A p.T373= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs146044034; called by muse, mutect2, varscan2
- FHOD1 | c.1488C>G p.P496= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- KIF16B | c.3951G>A p.G1317= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs753266659, COSV100734839; called by muse, mutect2, varscan2
